FM case AD10170 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/c99e2ba0-f9c8-40e2-8fef-40fdee0988ea

Female, 83.4 years: Non-small cell carcinoma (ICD-O-3 8046/3) of the lung; metastasis biopsied or resected from the pleura. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
